Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A45F, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A45F-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (20 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, ENCAPSULATED ONCOCYTIC FOLLICULAR VARIANT (1.5 CM) CONFINED TO RIGHT LOBE; NO ANGIOLYMPHATIC OR (tumoral-)CAPSULAR INVASION.
- B. PATHOLOGIC STAGE: pT1b NX.
- C. NODULAR THYROID HYPERPLASIA.

PART 2: PARATHYROID, ONE-FOURTH RIGHT INFERIOR, EXCISION (8 MG) -
NORMOCELLULAR PARATHYROID.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe
TUMOR FOCALITY:	Unifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE**:	Other: encapsulated oncocytic follicular variant
PRIMARY TUMOR (pT):	pT1b
REGIONAL LYMPH NODES (pN):	pNX
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Not identified
MARGINS:	Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified
ADDITIONAL PATHOLOGIC FINDINGS:	Other: nodular thyroid hyperplasia

ICD-0-3

carcinoma, papillary, NOS 8050/3
(Follicular + oncocytic mixed)

Site: thyroid, NOS C73.9

hw
9/28/12

IHPAA Discrepancy		☒

hw
8/28/12

Source: NCI Genomic Data Commons file 151e1eea-3b40-4fce-8e3f-bcd941f87036 (TCGA-BJ-A45F.E9C49C3D-87A7-418D-81CA-575C2B2CE62D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).